Gene-level copy-number profile of tumor specimen C3N-03886-03 from CPTAC case C3N-03886, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 60.3 years (22,042 days).
Specimen C3N-03886-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddf802d4-32e8-4ea1-99e7-879b286520a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03886-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,763 have no estimate.
https://portal.gdc.cancer.gov/files/ed1cdf15-e8db-48e4-9140-d0ea8c3a1245

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 20,840; copy number 2: 33,670; copy number 3: 1,304; copy number 4: 1,150; copy number 5: 1,514; copy number 6: 138; copy number 7: 34; copy number 8: 112; copy number 9: 9; copy number 11: 1; copy number 15: 9; copy number 25: 15; copy number 26: 3; copy number 37: 8; copy number 44: 10; copy number 50: 2.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr7:93,844,789–93,845,308, 1 gene (within-gene range 0–1): NDUFAF4P2.
- chr9:41,578,903–42,213,918, 18 genes: RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3.
- chr11:95,768,953–95,790,409, 1 gene (within-gene range 0–1): FAM76B.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,855 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,472,535–146,996,202, 70 genes, copy number 5 (broad region; genes not listed).
- chr1:147,902,795–175,335,459, 969 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr2:135,839,626–135,986,100, 3 genes, copy number 5 (within-gene range 4–5): MCM6, MANEALP1, DARS1.
- chr2:142,854,095–143,055,833, 3 genes, copy number 5: RRN3P4, KYNU, SFXN4P1.
- chr2:149,569,637–170,120,098, 239 genes, copy number 5 (broad region; genes not listed).
- chr3:119,428,949–123,028,605, 86 genes, copy number 5 (broad region; genes not listed).
- chr3:136,148,917–138,944,020, 46 genes, copy number 5–9 (within-gene range 5–12): MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391.
- chr3:139,003,962–151,928,175, 224 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr4:52,252,820–56,603,507, 88 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:19,323,428–19,839,080, 1 gene, copy number 6 (within-gene range 4–6): LNC-LBCS.
- chr6:19,612,755–21,523,783, 20 genes, copy number 6: KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1.
- chr11:69,737,298–70,436,584, 24 genes, copy number 11–37: DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:78,015,715–79,441,030, 24 genes, copy number 15–50 (within-gene range 3–50): AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1.
- chr14:18,333,726–18,626,787, 11 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5.
- chr19:31,348,881–31,417,794, 1 gene, copy number 5 (within-gene range 3–5): AC025809.1.
- chr19:31,421,997–33,225,850, 43 genes, copy number 5–7: AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4.
- chr21:12,999,676–13,067,033, 3 genes, copy number 6: AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 18,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
